TCGA case TCGA-LN-A5U7 — Esophageal Carcinoma (TCGA-ESCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Esophagus; Tissue source site: ILSBIO. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d67330ee-1791-4f5a-8996-8687a2d5cccb

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: Vietnam; Age at index: 46 years; Vital status: Alive; Country of birth: Vietnam.

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C15.4; Tissue or organ of origin: Middle third of esophagus; Site of resection or biopsy: Esophagus, NOS; Classification of tumor: primary; Age at diagnosis: 46.3 years (16,928 days); Year of diagnosis: 2012; Method of diagnosis: Biopsy; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Tumor grade: G1; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 768 days (2.1 years); Cancer detection method: Symptomatic; Sites of involvement: Esophagus, Middle Third.
   Pathology details: Consistent pathology review: Yes; Lymph node involvement: Negative.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel + Fluorouracil + Oxaliplatin; Days to treatment start: 537 days (1.5 years); Days to treatment end: 693 days (1.9 years); Treatment outcome: Complete Response.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Squamous cell carcinoma, NOS). Age at diagnosis: 47.8 years (17,463 days); Days to diagnosis: 535 days (1.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (4 entries)
- Days to follow up: 36 days; Disease response: Tumor Free.
- Day 535 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 535 days (1.5 years).
- Days to follow up: 768 days (2.1 years); Disease response: Tumor Free.
- Karnofsky performance status: 70.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 53 kg; Height: 169 cm; BMI: 18.6.

Exposures
- Alcohol history: Yes; Alcohol drinks per day: 1; Alcohol days per week: 7.
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 23; Age at onset: 23.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-LN-A5U7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 510 mg.
  Slide TCGA-LN-A5U7-01A-01-TSA: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 8; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample TCGA-LN-A5U7-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-LN-A5U7-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Tobacco smoking history indicator: 2; Alcohol consumption frequency: 7; History reflux disease indicator: No; History hpylori infection indicator: Never; History barretts esophageal indicator: No.
- Primary pathology: Esophageal tumor location centered: Mid; Histologic diagnosis: Esophagus Squamous Cell Carcinoma; Method initial path diagnosis: Endoscopic Biopsy; Lymph node sprd radiograph evidence: No; Lymph nodes examined: No.
- Primary pathology, Esophageal tumor involvement sites: Esophageal tumor location involved: Mid.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 768 days; disease-specific survival: no event (censored), 768 days; disease-free interval: event (new tumor event after initially disease-free), 535 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 535 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-LN-A5U7-01A-11D-A31T-01): tumor purity 0.77, ploidy 3.21, whole-genome doublings 1.
